Somatic mutation profile of tumor specimen MMRF_2593_1_BM_CD138pos (aliquot MMRF_2593_1_BM_CD138pos_T1_KHS5U_L12883) from MMRF case MMRF_2593, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.8 years (24,037 days).
Specimen MMRF_2593_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d74ace3f-793f-4d1a-a6ee-925be1750b1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2593_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2593_1_PB_Whole_C2_KHS5U_L12884; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4f8f07a-a521-44c1-90ae-f4ca4f5f437e

The open-access MAF lists 164 somatic variants for this specimen: 67 protein-altering or splice-affecting, 12 silent, 85 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 59, Missense Mutation 58, Intron 14, Silent 12, 5'UTR 6, Nonsense Mutation 5, 3'Flank 2, Frame Shift Del 2, RNA 2, 5'Flank 2, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.2501G>A p.R834H | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs758462294; called by muse, mutect2
- BIRC7 | c.865G>A p.V289I (on ENST00000217169 / NM_139317.3; = p.V271I on NM_022161.4) | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs748222291, COSV53901033; called by muse, mutect2, varscan2
- CYP4F2 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as rs762381741, COSV50001987; called by muse, mutect2, varscan2
- DACT2 | c.1852C>T p.R618W | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1028494879; called by muse, mutect2, varscan2
- ERC2 | c.982C>T p.R328* | Nonsense Mutation (SNP) | VAF 48/144 reads (33%) | catalogued as rs143061850; called by muse, mutect2, varscan2
- IGHV6-1 | c.168G>A p.W56* | Nonsense Mutation (SNP) | VAF 58/61 reads (95%) | catalogued as rs1555405753; called by muse, mutect2, varscan2
- IGLV3-1 | c.206A>T p.D69V | Missense Mutation (SNP) | VAF 74/134 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs373029284; called by muse, varscan2
- IGLV3-1 | c.292G>C p.A98P | Missense Mutation (SNP) | VAF 80/164 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as rs534241034; called by muse, varscan2
- JCAD | c.1931G>A p.R644K | Missense Mutation (SNP) | VAF 92/221 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV64760820; called by muse, mutect2, varscan2
- LRPPRC | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1480336139; called by muse, mutect2, varscan2
- MASP2 | c.932T>G p.V311G | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV68896959; called by muse, mutect2, varscan2
- MKI67 | c.6347G>T p.S2116I | Missense Mutation (SNP) | VAF 10/203 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); catalogued as COSV64075816; called by muse, mutect2
- MYH14 | c.5044C>T p.R1682C | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs778251472; called by muse, mutect2, varscan2
- MYO3A | c.742C>G p.P248A | Missense Mutation (SNP) | VAF 112/313 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56348338; called by muse, mutect2, varscan2
- MZT2B | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs138130291; called by muse, mutect2, varscan2
- NUP214 | c.2350G>A p.E784K | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.121); catalogued as rs754885807; called by muse, mutect2, varscan2
- PAK5 | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.631); catalogued as rs201196548, COSV100781341; called by muse, mutect2
- PARP12 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV54932767; called by muse, mutect2, varscan2
- PTPN14 | c.2037G>T p.E679D | Missense Mutation (SNP) | VAF 73/426 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV65289620; called by muse, varscan2
- SERPINB4 | c.226G>C p.D76H | Missense Mutation (SNP) | VAF 53/103 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV61986159; called by muse, mutect2, varscan2
- STPG2 | c.1142del p.R381Kfs*14 | Frame Shift Del (DEL) | VAF 73/193 reads (38%) | catalogued as COSV54787407; called by mutect2, pindel, varscan2
- TENT5D | c.89A>G p.K30R | Missense Mutation (SNP) | VAF 60/63 reads (95%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100382607; called by muse, mutect2, varscan2
- TNR | c.3264T>G p.D1088E | Missense Mutation (SNP) | VAF 86/539 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs765081683, COSV99688877; called by muse, mutect2, varscan2
- TRBV6-1 | c.170A>T p.D57V | Missense Mutation (SNP) | VAF 64/187 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs750869392; called by muse, mutect2, varscan2
- UBL4B | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 81/186 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs372349264; called by muse, mutect2, varscan2
- ZFHX4 | c.2497G>A p.G833R | Missense Mutation (SNP) | VAF 65/151 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1389952483, COSV99269424; called by muse, mutect2, varscan2
- ARHGAP12 | c.1951+4G>A | Splice Region (SNP) | VAF 42/82 reads (51%) | called by muse, mutect2, varscan2
- ARMH3 | c.1763A>T p.H588L | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ART4 | c.520A>G p.S174G | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- BCL11B | c.1033T>A p.F345I (on ENST00000357195 / NM_001282237.2; = p.F274I on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/38 reads (84%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CMPK2 | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTLN | c.1384G>C p.V462L | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- COL6A2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 42/91 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRACD | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 138/284 reads (49%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- DAB1 | c.1284C>A p.D428E (on ENST00000371231; = p.D395E on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 89/209 reads (43%) | SIFT tolerated (0.79); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- DACT1 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 179/396 reads (45%) | called by muse, mutect2, varscan2
- GOLPH3 | c.566C>T p.T189I | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- HIPK1 | c.1181G>A p.G394D | Missense Mutation (SNP) | VAF 103/316 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HIPK3 | c.995A>G p.D332G | Missense Mutation (SNP) | VAF 75/198 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- HS3ST5 | c.451A>C p.I151L | Missense Mutation (SNP) | VAF 139/193 reads (72%) | SIFT tolerated (0.6); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- IGKJ4 | chr2:88860915 del AAAGTGAGC | Missense Mutation (DEL) | VAF 25/78 reads (32%) | called by pindel, varscan2
- KCNN1 | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 253/385 reads (66%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- KIAA0319 | c.1273A>G p.K425E | Missense Mutation (SNP) | VAF 79/273 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- KIF16B | c.1668A>T p.E556D | Missense Mutation (SNP) | VAF 82/170 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LRRC38 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- LRRK2 | c.7283G>A p.G2428E | Missense Mutation (SNP) | VAF 82/286 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NINL | c.2339A>T p.E780V | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.026); called by muse, mutect2
- NR5A2 | c.250G>C p.E84Q (on ENST00000367362 / NM_205860.3; = p.E38Q on NM_003822.5) | Missense Mutation (SNP) | VAF 71/494 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- OR6C3 | c.298_299del p.F100Lfs*8 | Frame Shift Del (DEL) | VAF 25/167 reads (15%) | called by mutect2, pindel, varscan2
- OR9Q2 | c.44C>A p.T15N | Missense Mutation (SNP) | VAF 76/158 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.08); called by muse, varscan2
- PCDH15 | c.5018C>A p.T1673N | Missense Mutation (SNP) | VAF 95/269 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- PNPLA7 | c.2027C>G p.T676R | Missense Mutation (SNP) | VAF 115/458 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- PPFIA4 | c.2705C>A p.P902H (on ENST00000447715; = p.P903H on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/299 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); called by muse, mutect2
- PRSS58 | c.46T>A p.L16M | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- PTPRB | c.280A>G p.T94A | Missense Mutation (SNP) | VAF 92/165 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- RAD54L2 | c.2091C>A p.N697K | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- RINT1 | c.1559T>G p.L520* | Nonsense Mutation (SNP) | VAF 116/271 reads (43%) | called by muse, mutect2, varscan2
- RNF217 | c.837G>T p.K279N | Missense Mutation (SNP) | VAF 103/145 reads (71%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RUNX1T1 | c.191G>T p.G64V (on ENST00000265814 / NM_001198628.1; = p.G37V on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- SHANK1 | c.6335T>C p.L2112S | Missense Mutation (SNP) | VAF 107/322 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SHC4 | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 76/189 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- SLC35F4 | c.916A>C p.I306L (on ENST00000339762 / NM_001352015.2; = p.I270L on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- TAF2 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 78/199 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- TAOK1 | c.422A>G p.Y141C | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRBV4-2 | c.21C>A p.C7* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- VNN1 | c.819A>T p.K273N | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF804B | c.432G>T p.K144N | Missense Mutation (SNP) | VAF 146/337 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3744C>T p.A1248= | Silent (SNP) | VAF 20/57 reads (35%) | called by muse, mutect2, varscan2
- FPGT | c.465G>A p.Q155= | Silent (SNP) | VAF 9/94 reads (10%) | called by muse, mutect2
- FTMT | c.627T>A p.G209= | Silent (SNP) | VAF 96/206 reads (47%) | called by muse, mutect2, varscan2
- LMNB2 | c.1354C>T p.L452= | Silent (SNP) | VAF 82/228 reads (36%) | catalogued as rs772768993; called by muse, varscan2
- OR7E24 | c.108A>G p.S36= | Silent (SNP) | VAF 37/64 reads (58%) | called by muse, mutect2, varscan2
- RDH14 | c.906C>T p.Y302= | Silent (SNP) | VAF 19/302 reads (6%) | catalogued as COSV67118789; called by muse, mutect2
- RTL5 | c.1182G>A p.E394= | Silent (SNP) | VAF 38/41 reads (93%) | called by muse, mutect2, varscan2
- TRAPPC12 | c.2091G>A p.L697= | Silent (SNP) | VAF 91/212 reads (43%) | catalogued as COSV60846336; called by muse, mutect2, varscan2
- TSPOAP1 | c.5232G>A p.S1744= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as rs139473278, COSV99271020; called by muse, mutect2, varscan2
- UNC5C | c.2010A>T p.V670= | Silent (SNP) | VAF 39/78 reads (50%) | called by muse, mutect2, varscan2
- ZMIZ2 | c.459G>A p.V153= | Silent (SNP) | VAF 40/113 reads (35%) | called by muse, mutect2, varscan2
- ZNF831 | c.2544G>A p.T848= | Silent (SNP) | VAF 52/156 reads (33%) | catalogued as rs779808178, COSV64042556; called by muse, mutect2, varscan2
- ADAM23 | c.*898G>A | 3'UTR (SNP) | VAF 48/104 reads (46%) | called by muse, mutect2, varscan2
- AGR2 | c.*46T>G | 3'UTR (SNP) | VAF 105/120 reads (88%) | called by muse, mutect2, varscan2
- ARHGAP20 | c.*1403A>T | 3'UTR (SNP) | VAF 57/122 reads (47%) | called by muse, mutect2, varscan2
- ARL4C | c.*2310A>T | 3'UTR (SNP) | VAF 28/63 reads (44%) | called by muse, mutect2, varscan2
- ASPHD1 | c.*76C>T | 3'UTR (SNP) | VAF 63/129 reads (49%) | called by muse, mutect2, varscan2
- ATP11A | c.*935G>C | 3'UTR (SNP) | VAF 57/121 reads (47%) | called by muse, mutect2, varscan2
- ATP11A | c.*936G>T | 3'UTR (SNP) | VAF 56/122 reads (46%) | called by muse, mutect2, varscan2
- BMP5 | c.*1734T>C | 3'UTR (SNP) | VAF 25/57 reads (44%) | called by muse, mutect2, varscan2
- CALN1 | c.*8227G>T | 3'UTR (SNP) | VAF 36/69 reads (52%) | called by muse, mutect2, varscan2
- CAPN8 | chr1:223538086 G>T | 3'Flank (SNP) | VAF 79/388 reads (20%) | called by muse, mutect2, varscan2
- CBLN4 | c.*113G>T | 3'UTR (SNP) | VAF 49/191 reads (26%) | called by muse, mutect2, varscan2
- CCDC85A | c.*1101_*1102dup | 3'UTR (INS) | VAF 32/74 reads (43%) | called by mutect2, varscan2
- CCDC88C | c.*100G>A | 3'UTR (SNP) | VAF 57/66 reads (86%) | called by muse, mutect2, varscan2
- CDC23 | c.372+500C>G | Intron (SNP) | VAF 21/42 reads (50%) | called by muse, mutect2, varscan2
- CECR2 | c.*465C>A | 3'UTR (SNP) | VAF 11/17 reads (65%) | called by muse, mutect2, varscan2
- CNOT6 | c.*170C>G | 3'UTR (SNP) | VAF 29/47 reads (62%) | called by muse, mutect2, varscan2
- CXCL12 | c.*1154G>C | 3'UTR (SNP) | VAF 34/85 reads (40%) | called by muse, mutect2, varscan2
- DEK | c.*1391C>A | 3'UTR (SNP) | VAF 55/123 reads (45%) | called by muse, mutect2, varscan2
- DEK | c.*844T>C | 3'UTR (SNP) | VAF 45/95 reads (47%) | called by muse, mutect2, varscan2
- DENND11 | c.*5704T>G | 3'UTR (SNP) | VAF 9/143 reads (6%) | called by muse, mutect2
- DNAAF1 | c.1645-76T>G | Intron (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- EGLN3 | c.357+2109C>G | Intron (SNP) | VAF 25/70 reads (36%) | called by muse, mutect2, varscan2
- EHBP1L1 | c.-158G>A | 5'UTR (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- EIF5A2 | c.*1562A>G | 3'UTR (SNP) | VAF 29/67 reads (43%) | called by muse, mutect2, varscan2
- ELK4 | c.*1051G>C | 3'UTR (SNP) | VAF 6/124 reads (5%) | called by muse, mutect2
- ENSA | c.*607G>A | 3'UTR (SNP) | VAF 97/123 reads (79%) | called by muse, mutect2, varscan2
- FAM163A | c.*1818C>A | 3'UTR (SNP) | VAF 22/502 reads (4%) | called by muse, mutect2
- FBXL19 | c.*1523T>C | 3'UTR (SNP) | VAF 57/116 reads (49%) | called by muse, mutect2, varscan2
- FHOD3 | c.1197-4675T>C | Intron (SNP) | VAF 117/245 reads (48%) | called by muse, mutect2, varscan2
- GAB1 | chr4:143473205 A>T | 3'Flank (SNP) | VAF 40/92 reads (43%) | called by muse, mutect2, varscan2
- GABRB2 | c.*2556A>T | 3'UTR (SNP) | VAF 32/71 reads (45%) | called by muse, mutect2, varscan2
- GAREM2 | c.*836C>G | 3'UTR (SNP) | VAF 16/239 reads (7%) | called by muse, mutect2
- GPR180 | c.-17C>T | 5'UTR (SNP) | VAF 18/36 reads (50%) | called by muse, mutect2, varscan2
- HES1 | c.*182G>T | 3'UTR (SNP) | VAF 7/108 reads (6%) | called by muse, mutect2
- HMCN1 | c.*103T>A | 3'UTR (SNP) | VAF 18/94 reads (19%) | called by muse, mutect2, varscan2
- IL1R1 | c.*2709C>A | 3'UTR (SNP) | VAF 52/146 reads (36%) | called by muse, mutect2, varscan2
- ITGB3 | c.*426C>T | 3'UTR (SNP) | VAF 37/97 reads (38%) | called by muse, mutect2, varscan2
- KCNIP4 | c.288+96C>A | Intron (SNP) | VAF 5/9 reads (56%) | called by muse, mutect2, varscan2
- KDM8 | c.*234G>A | 3'UTR (SNP) | VAF 27/66 reads (41%) | called by muse, mutect2, varscan2
- KMT2C | c.*425C>G | 3'UTR (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- KMT2C | c.*298C>T | 3'UTR (SNP) | VAF 16/28 reads (57%) | called by muse, varscan2
- LIMA1 | c.865-22dup | Intron (INS) | VAF 48/147 reads (33%) | called by mutect2, pindel, varscan2
- LRCH3 | c.2209-2864C>T | Intron (SNP) | VAF 66/142 reads (46%) | catalogued as COSV101367917; called by muse, mutect2, varscan2
- MEOX2 | c.*199G>T | 3'UTR (SNP) | VAF 60/63 reads (95%) | catalogued as rs1018262163; called by muse, mutect2, varscan2
- MIR16-1 | chr13:50049215 A>T | 5'Flank (SNP) | VAF 6/8 reads (75%) | called by mutect2, varscan2
- MNT | c.*713C>T | 3'UTR (SNP) | VAF 46/92 reads (50%) | called by muse, mutect2, varscan2
- MTMR9 | c.*2251C>A | 3'UTR (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- NCOA1 | c.*1889G>A | 3'UTR (SNP) | VAF 42/102 reads (41%) | called by muse, mutect2, varscan2
- NPAP1 | c.*230T>C | 3'UTR (SNP) | VAF 32/80 reads (40%) | catalogued as COSV100275419; called by muse, mutect2, varscan2
- NUDCD2 | c.-37T>C | 5'UTR (SNP) | VAF 42/73 reads (58%) | catalogued as rs1412431060; called by muse, mutect2, varscan2
- OR4P4 | c.*63T>A | 3'UTR (SNP) | VAF 54/134 reads (40%) | called by muse, mutect2, varscan2
- PAPPA | c.*3314T>G | 3'UTR (SNP) | VAF 50/117 reads (43%) | called by muse, mutect2, varscan2
- PFN2 | c.-102C>A | 5'UTR (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- PLPP6 | c.*934A>T | 3'UTR (SNP) | VAF 36/138 reads (26%) | called by muse, mutect2, varscan2
- POU5F1B | c.*1887T>C | 3'UTR (SNP) | VAF 31/81 reads (38%) | called by muse, mutect2, varscan2
- PTGFR | c.*2792C>T | 3'UTR (SNP) | VAF 67/124 reads (54%) | called by muse, mutect2, varscan2
- PTPRC | c.*327C>A | 3'UTR (SNP) | VAF 127/232 reads (55%) | called by muse, mutect2, varscan2
- PVR | c.-146C>T | 5'UTR (SNP) | VAF 29/78 reads (37%) | called by muse, mutect2, varscan2
- RAB38 | c.*105G>A | 3'UTR (SNP) | VAF 196/440 reads (45%) | called by muse, mutect2
- RBM12 | c.*283T>C | 3'UTR (SNP) | VAF 7/91 reads (8%) | called by muse, mutect2
- RNY4P30 | chr13:49892269 G>C | 5'Flank (SNP) | VAF 71/94 reads (76%) | called by muse, mutect2, varscan2
- SFTPC | c.435+131T>C | Intron (SNP) | VAF 133/309 reads (43%) | catalogued as rs533650743; called by muse, mutect2, varscan2
- SIAE | c.*661A>T | 3'UTR (SNP) | VAF 43/92 reads (47%) | called by muse, mutect2, varscan2
- SLC15A3 | c.1592-149A>C | Intron (SNP) | VAF 102/220 reads (46%) | catalogued as rs777447076; called by muse, mutect2, varscan2
- SLF1 | c.*1034T>A | 3'UTR (SNP) | VAF 14/31 reads (45%) | called by muse, mutect2, varscan2
- SLITRK2 | c.-3248C>T | 5'UTR (SNP) | VAF 37/101 reads (37%) | called by muse, mutect2, varscan2
- SNX29 | c.1402+9003G>C | Intron (SNP) | VAF 62/148 reads (42%) | called by muse, mutect2, varscan2
- SOD3 | c.*436C>A | 3'UTR (SNP) | VAF 78/152 reads (51%) | called by muse, mutect2, varscan2
- SP9 | c.22-107G>A | Intron (SNP) | VAF 13/26 reads (50%) | called by muse, mutect2, varscan2
- SRGAP1 | c.1408+158C>T | Intron (SNP) | VAF 20/42 reads (48%) | called by muse, mutect2, varscan2
- STAC | c.*1557C>A | 3'UTR (SNP) | VAF 53/118 reads (45%) | called by muse, mutect2, varscan2
- STMN2 | c.*619G>A | 3'UTR (SNP) | VAF 125/376 reads (33%) | catalogued as rs1437077364; called by muse, mutect2, varscan2
- TANGO2 | c.*22G>T | 3'UTR (SNP) | VAF 56/119 reads (47%) | called by muse, mutect2, varscan2
- TBC1D12 | c.*1446A>G | 3'UTR (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- TEX261 | c.*639C>G | 3'UTR (SNP) | VAF 56/112 reads (50%) | called by muse, mutect2, varscan2
- TMEM199 | c.*1642T>C | 3'UTR (SNP) | VAF 32/77 reads (42%) | catalogued as rs1360034009; called by muse, mutect2, varscan2
- TRA2B | c.*1236T>C | 3'UTR (SNP) | VAF 42/109 reads (39%) | called by muse, mutect2, varscan2
- TRMT10B | c.*1223C>T | 3'UTR (SNP) | VAF 56/195 reads (29%) | called by muse, mutect2, varscan2
- TTLL10 | c.119-141G>A | Intron (SNP) | VAF 16/26 reads (62%) | catalogued as rs1480793778; called by muse, mutect2, varscan2
- VGLL3 | c.*5767A>C | 3'UTR (SNP) | VAF 33/66 reads (50%) | called by muse, mutect2, varscan2
- ZNF197 | c.*612T>C | 3'UTR (SNP) | VAF 8/12 reads (67%) | catalogued as rs1350922639; called by muse, mutect2, varscan2
- ZNF34 | c.96+70G>T | Intron (SNP) | VAF 61/119 reads (51%) | called by muse, mutect2, varscan2
- ZNF573 | c.*133A>T | 3'UTR (SNP) | VAF 15/27 reads (56%) | called by muse, mutect2, varscan2
- ZNF733P | n.152A>C | RNA (SNP) | VAF 107/267 reads (40%) | called by muse, mutect2, varscan2
- ZNF812P | n.1844C>A | RNA (SNP) | VAF 43/140 reads (31%) | called by muse, mutect2, varscan2
